Somatic mutation profile of tumor specimen TCGA-DD-AAD2-01A (aliquot TCGA-DD-AAD2-01A-11D-A40R-10) from TCGA case TCGA-DD-AAD2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.3 years (24,221 days).
Specimen TCGA-DD-AAD2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e6b5960-46b6-4792-a10c-f24c8a386140.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAD2-10A (Blood Derived Normal), aliquot TCGA-DD-AAD2-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1efcf630-9753-4ac5-a2ae-e45c4f236826

The open-access MAF lists 90 somatic variants for this specimen: 68 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 19, Nonsense Mutation 5, Frame Shift Ins 2, Intron 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 120/304 reads (39%) | catalogued as rs1557396632, CM159873, COSV55902813, COSV55906108; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2223G>T p.K741N | Missense Mutation (SNP) | VAF 46/241 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59216574, COSV59220599; called by muse, mutect2, varscan2
- ADAM17 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100176517; called by muse, mutect2, varscan2
- ADGRG1 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV101113556; called by muse, mutect2
- AFF4 | c.425G>C p.S142T | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as COSV99535373; called by muse, mutect2, varscan2
- AKAP6 | c.3942G>T p.M1314I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1344566091, COSV99804256; called by muse, mutect2, varscan2
- APOB | c.9799A>C p.M3267L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV99267912; called by muse, mutect2, varscan2
- ARTN | c.463C>G p.R155G (on ENST00000372354; = p.R163G on NM_057090.2) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as COSV100964362; called by muse, mutect2, varscan2
- BRD8 | c.3655A>G p.S1219G | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV99496971; called by muse, mutect2
- C1orf100 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs764037259, COSV100353486; called by muse, mutect2, varscan2
- CACNA1D | c.6389T>C p.L2130P (on ENST00000350061 / NM_001128840.3; = p.L2150P on NM_000720.4) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.642); catalogued as COSV99859594; called by muse, mutect2, varscan2
- CACTIN | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99698863; called by muse, mutect2, varscan2
- CC2D1A | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV100528687; called by muse, mutect2, varscan2
- CD82 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs771739391, COSV99907613; called by muse, mutect2, varscan2
- CNP | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV101103050; called by muse, mutect2, varscan2
- COL19A1 | c.2753C>A p.P918Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs201916147, COSV100507461, COSV59576680; called by muse, mutect2, varscan2
- CSMD3 | c.6293G>T p.R2098I (on ENST00000297405 / NM_001363185.1; = p.R1994I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99846895; called by muse, mutect2
- CSMD3 | c.2290A>G p.N764D (on ENST00000297405 / NM_001363185.1; = p.N660D on NM_052900.3) | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99846897; called by muse, mutect2, varscan2
- DAZAP1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99245465; called by muse, mutect2, varscan2
- DHX9 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100841514; called by muse, mutect2, varscan2
- DNAJC16 | c.1295A>T p.D432V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV101012653; called by muse, mutect2, varscan2
- DYNC1LI2 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV99263252; called by muse, mutect2, varscan2
- EIF2B3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100838985; called by muse, mutect2, varscan2
- EPDR1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as rs913532789, COSV99554662; called by muse, mutect2, varscan2
- EYS | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 74/387 reads (19%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.624); catalogued as rs758660747, COSV60977268, COSV60982026, COSV61002672; called by muse, varscan2
- F5 | c.4805A>G p.D1602G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV100889228; called by muse, mutect2, varscan2
- FAM174A | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); catalogued as rs1561309844, COSV100444608; called by muse, mutect2, varscan2
- FBXW5 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.776); catalogued as COSV99812679; called by muse, mutect2, varscan2
- FGD6 | c.4223T>G p.V1408G | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100676796; called by muse, varscan2
- FGD6 | c.4174T>G p.S1392A | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV100676798; called by muse, varscan2
- FOCAD | c.1757C>G p.A586G | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100620685; called by muse, mutect2, varscan2
- FOXP1 | c.1550T>G p.L517R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100562331; called by muse, mutect2, varscan2
- HEATR3 | c.1119G>A p.M373I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV99590111; called by muse, mutect2
- IK | c.16A>T p.S6C | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.157); catalogued as COSV99347395; called by muse, mutect2, varscan2
- KIF2A | c.2042T>A p.V681E | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99551204; called by muse, mutect2, varscan2
- MTUS2 | c.2935C>T p.R979* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | catalogued as rs752848300, COSV70914696; called by muse, mutect2, varscan2
- NBEA | c.5899G>T p.G1967* | Nonsense Mutation (SNP) | VAF 33/200 reads (17%) | catalogued as COSV100083981; called by muse, mutect2, varscan2
- NBEA | c.5900G>T p.G1967V | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083984, COSV59822487; called by muse, mutect2, varscan2
- NHLH2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV57202451; called by muse, mutect2, varscan2
- NKPD1 | c.1888C>T p.P630S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs776696719; called by muse, mutect2
- PCDHA12 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as rs17844352, COSV56491917, COSV56505360; called by muse, mutect2, varscan2
- PDE8A | c.829A>T p.N277Y | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV100052332; called by muse, mutect2, varscan2
- PSAP | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1165032545, COSV67549668; called by mutect2, varscan2
- RFWD3 | c.882G>A p.W294* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100736316; called by muse, mutect2, varscan2
- SCRIB | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs994549931, COSV100254089; called by muse, mutect2, varscan2
- SHPRH | c.387A>C p.L129F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.463); catalogued as COSV99262657; called by muse, mutect2, varscan2
- SLC5A11 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768485681, COSV61739771; called by muse, mutect2, varscan2
- SLCO3A1 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV59231265; called by muse, mutect2, varscan2
- SPZ1 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99698272; called by muse, mutect2, varscan2
- STON1 | c.1552A>T p.K518* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV100562275; called by muse, mutect2, varscan2
- SYNE1 | c.1450G>T p.D484Y (on ENST00000367255 / NM_182961.4; = p.D491Y on NM_033071.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99577736; called by muse, mutect2, varscan2
- TAS1R2 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs368636486; called by muse, mutect2, varscan2
- TFAP2B | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99540840; called by muse, varscan2
- TG | c.4754C>A p.A1585D | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55094057, COSV99603064; called by muse, mutect2, varscan2
- TMEM132E | c.869C>T p.P290L (on ENST00000321639; = p.P380L on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1389721678, COSV100396765; called by muse, mutect2, varscan2
- TMEM236 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100592583; called by muse, mutect2, varscan2
- TNRC6B | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100110462; called by muse, mutect2, varscan2
- TPPP2 | c.123T>A p.D41E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100069463; called by muse, mutect2, varscan2
- TRIM29 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs767234514, COSV100532005; called by muse, mutect2, varscan2
- TTN | c.61087G>A p.A20363T (on ENST00000591111; = p.A12939T on NM_003319.4) | Missense Mutation (SNP) | VAF 39/167 reads (23%) | PolyPhen possibly damaging (0.558); catalogued as COSV60329491; called by muse, mutect2, varscan2
- WNK2 | c.6079G>A p.A2027T (on ENST00000297954 / NM_001282394.1; = p.A1990T on NM_006648.3) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.867); catalogued as COSV99944446; called by muse, mutect2, varscan2
- YAF2 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100586470; called by muse, mutect2, varscan2
- ZAP70 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99385922; called by muse, varscan2
- ZNF502 | c.459dup p.S154Ifs*5 | Frame Shift Ins (INS) | VAF 39/255 reads (15%) | catalogued as rs757972659; called by mutect2, pindel, varscan2
- ZNF560 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV100038692, COSV56871200; called by muse, mutect2
- ZNF804A | c.2729T>G p.V910G | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV56471560; called by muse, mutect2, varscan2
- CCN6 | c.885_886del p.F295Lfs*7 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- KIF7 | c.2825dup p.L943Pfs*105 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel
- AOX1 | c.75A>G p.T25= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV101022226; called by muse, mutect2, varscan2
- C1orf115 | c.369C>T p.F123= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs775578543, COSV54273764; called by muse, mutect2, varscan2
- C6orf118 | c.381G>T p.P127= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs202048007, COSV100025130, COSV57816185; called by muse, mutect2, varscan2
- DLG4 | c.522C>T p.I174= (on ENST00000399506 / NM_001321075.3; = p.I217= on NM_001365.4) | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs746539810, COSV57241843; called by muse, mutect2, varscan2
- FSTL5 | c.861T>C p.I287= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100060758; called by muse, mutect2, varscan2
- GRAMD1B | c.636G>A p.K212= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100454861, COSV100455204; called by muse, mutect2, varscan2
- GRIN2D | c.1515C>G p.L505= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV99616938; called by muse, mutect2, varscan2
- LILRB3 | c.9C>T p.P3= | Silent (SNP) | VAF 59/498 reads (12%) | catalogued as rs566409321, COSV54427816; called by muse, mutect2, varscan2
- MMP19 | c.378G>A p.R126= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100491240, COSV59453044; called by muse, mutect2, varscan2
- MVD | c.627A>T p.T209= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1389198883, COSV99880144; called by muse, mutect2, varscan2
- PCDH9 | c.3489C>A p.P1163= (on ENST00000377865 / NM_203487.3; = p.P1129= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV100123363; called by muse, mutect2, varscan2
- PCDHA3 | c.573C>T p.S191= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs1554121681, COSV65371283; called by muse, mutect2, varscan2
- PEG3 | c.4329C>G p.A1443= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV55624172, COSV55640348, COSV55641484; called by muse, mutect2, varscan2
- RAPGEF3 | c.1701A>T p.P567= (on ENST00000389212; = p.P525= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99406818; called by muse, mutect2, varscan2
- RASGEF1A | c.921C>T p.I307= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs772673426, COSV65667699; called by muse, mutect2, varscan2
- ROBO3 | c.3030G>A p.T1010= | Silent (SNP) | VAF 154/731 reads (21%) | catalogued as rs1318590034, COSV101185189; called by muse, mutect2, varscan2
- TDRD10 | c.996G>T p.G332= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV52726472, COSV99427661; called by muse, mutect2, varscan2
- WDR36 | c.1599C>T p.G533= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV72605115; called by muse, mutect2, varscan2
- ZSCAN5A | c.381A>G p.K127= | Silent (SNP) | VAF 22/267 reads (8%) | catalogued as COSV99570655; called by muse, mutect2
- ADGRA2 | c.*2133C>A | 3'UTR (SNP) | VAF 47/177 reads (27%) | catalogued as COSV99605114; called by muse, mutect2, varscan2
- DST | c.4297-1511A>C | Intron (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99759743; called by muse, mutect2, varscan2
- SYNE1 | c.23628-3795dup | Intron (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
